Somatic mutation profile of tumor specimen TCGA-D1-A1NZ-01A (aliquot TCGA-D1-A1NZ-01A-21D-A14G-09) from TCGA case TCGA-D1-A1NZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 60.3 years (22,027 days).
Specimen TCGA-D1-A1NZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 353c906c-e8c2-4afa-84af-00a34e548958.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A1NZ-10A (Blood Derived Normal), aliquot TCGA-D1-A1NZ-10A-01D-A14G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d35d61e4-0d49-40b6-9e5e-01d676f77135

The open-access MAF lists 904 somatic variants for this specimen: 677 protein-altering or splice-affecting, 197 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 458, Silent 197, Frame Shift Del 147, Frame Shift Ins 30, Nonsense Mutation 25, Intron 12, RNA 10, Splice Site 9, In Frame Del 6, 3'Flank 4, 3'UTR 3, 5'UTR 1.

Variants (750 of 904; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | hotspot (GDC flag); catalogued as COSV61370466; called by muse, mutect2, varscan2
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- CTC1 | c.2996dup p.E1000* | Frame Shift Ins (INS) | VAF 7/19 reads (37%) | catalogued as rs1567599993; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CTCF | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs968244943, COSV50461455; ClinVar: uncertain significance; called by muse, mutect2
- FRMPD4 | c.1851del p.C618Vfs*8 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs886038208; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IQSEC2 | c.848del p.G283Afs*23 (on ENST00000642864 / NM_001111125.3; = p.G78Afs*23 on NM_015075.2) | Frame Shift Del (DEL) | VAF 11/50 reads (22%) | catalogued as rs782660318, COSV64726734; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 7/23 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 33/38 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SACS | c.3328del p.I1110Lfs*16 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs770866403; ClinVar: likely pathogenic; called by mutect2, varscan2
- USH2A | c.14911C>T p.R4971* | Nonsense Mutation (SNP) | VAF 25/114 reads (22%) | catalogued as rs397517994, CM1110189, COSV56364393; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.342dup p.Q115Tfs*3 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | catalogued as rs376463919; called by mutect2, varscan2
- ABCA13 | c.13436G>T p.R4479M | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101291462; called by muse, mutect2, varscan2
- ABCA2 | c.3176C>T p.A1059V (on ENST00000614293; = p.A1029V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688628; called by muse, mutect2
- ABCA7 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99566813; called by muse, mutect2, varscan2
- ABCA7 | c.5329G>A p.A1777T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.206); catalogued as COSV99566815; called by muse, mutect2, varscan2
- ACTR3 | c.102T>C p.C34= | Splice Region (SNP) | VAF 7/43 reads (16%) | catalogued as rs201769858, COSV99604091; called by muse, mutect2, varscan2
- ACY3 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV99663208; called by muse, mutect2, varscan2
- ADAMTS18 | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99274614; called by muse, mutect2, varscan2
- ADAMTS8 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs369424623, COSV57298542; called by muse, mutect2, varscan2
- ADD1 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs777763271, COSV53276915; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 6/11 reads (55%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB1 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV100030561; called by muse, mutect2, varscan2
- ADGRG1 | c.1205A>G p.Y402C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs906181049, COSV101113599; called by muse, mutect2, varscan2
- ADNP | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.935); catalogued as rs1251827956, COSV100823894; called by muse, mutect2, varscan2
- AFF1 | c.3266A>G p.Q1089R | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100321157; called by muse, mutect2, varscan2
- AJAP1 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100982066; called by muse, mutect2, varscan2
- ALDH1L1 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs768309358, COSV56414649; called by muse, mutect2, varscan2
- ALDH3B2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100824160; called by muse, mutect2, varscan2
- ALG1 | c.434G>A p.G145D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs387906926, CM107160, COSV99276082; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMELX | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV61634203; called by mutect2, varscan2
- ANK2 | c.2444T>C p.V815A | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1396611769, COSV100004712; called by muse, mutect2, varscan2
- ANKRD13A | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1263330241, COSV55677125; called by muse, mutect2, varscan2
- ANO8 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50191960; called by muse, mutect2, varscan2
- APOB | c.2329C>A p.L777I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99267907; called by muse, mutect2, varscan2
- ARFGEF2 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.76); PolyPhen benign (0.04); catalogued as COSV100904547; called by muse, mutect2
- ARHGAP39 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.073); catalogued as COSV99432450; called by muse, mutect2, varscan2
- ARHGEF15 | c.1949del p.G650Afs*145 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as COSV62725865; called by mutect2, pindel, varscan2
- ARHGEF2 | c.1582G>A p.V528I (on ENST00000361247 / NM_001162383.2; = p.V500I on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs765138663, COSV58112395; called by muse, mutect2, varscan2
- ARHGEF2 | c.1351C>A p.P451T (on ENST00000361247 / NM_001162383.2; = p.P423T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.543); catalogued as COSV100561297; called by muse, mutect2, varscan2
- ARHGEF4 | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.573); catalogued as COSV100388890; called by muse, mutect2, varscan2
- ARHGEF40 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as COSV100070780; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs201178069; called by pindel, varscan2
- ARMC5 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99192907; called by muse, mutect2, varscan2
- ARMC5 | c.2408T>G p.V803G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV99192909; called by muse, mutect2, varscan2
- ARMH3 | c.57del p.K19Nfs*3 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs1564877323; called by mutect2, pindel, varscan2
- ARV1 | c.771G>T p.W257C | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100048669; called by muse, mutect2
- ATG2B | c.1727T>G p.L576R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100738349; called by muse, mutect2, varscan2
- ATP1B1 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs147107209; called by muse, mutect2
- ATP4B | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV100089984; called by muse, mutect2, varscan2
- BAIAP2 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100349055; called by muse, mutect2, varscan2
- BCL6B | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs754062790, COSV53426184; called by muse, mutect2, varscan2
- BCORL1 | c.3289G>A p.G1097R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99501248; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as rs776003776; called by mutect2, pindel, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRAT1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.13); catalogued as rs749451094, COSV61395560; called by muse, mutect2, varscan2
- BRCA2 | c.7517A>G p.Q2506R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101204708; called by muse, mutect2, varscan2
- BTAF1 | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56431068, COSV99795941; called by muse, mutect2, varscan2
- BUB1B | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as CM060204, COSV55016309; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, varscan2
- C2CD3 | c.4241T>G p.L1414R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100487608; called by muse, mutect2
- C3orf84 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100234357; called by muse, mutect2, varscan2
- CABYR | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.108); catalogued as rs199508229, COSV100510226; called by muse, varscan2
- CACNA1S | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs777247285, COSV62941024; called by muse, mutect2, varscan2
- CALCB | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV100158169; called by muse, mutect2, varscan2
- CAMK2D | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1227223871, COSV99595024; called by muse, varscan2
- CAMKMT | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.761); catalogued as rs201075899, COSV65923575; called by muse, mutect2, varscan2
- CAMTA1 | c.2429C>T p.A810V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.041); catalogued as rs768327327, COSV100352303, COSV57879328; called by muse, mutect2, varscan2
- CASC3 | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); catalogued as COSV99230082; called by muse, mutect2, varscan2
- CASD1 | c.1626del p.A543Qfs*13 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs770159446; called by mutect2, varscan2
- CBLN2 | c.625G>T p.G209W | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328076518, COSV99504721; called by muse, mutect2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CC2D2A | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.999); catalogued as rs566281691, COSV101052992; called by muse, mutect2
- CCDC120 | c.863C>T p.T288I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV100900740; called by muse, mutect2, varscan2
- CCDC136 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99923380; called by muse, mutect2, varscan2
- CCDC136 | c.2188C>T p.L730F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as rs1266212587, COSV99923384; called by muse, mutect2, varscan2
- CCDC142 | c.59G>T p.R20M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.35); catalogued as COSV51778397, COSV99282436; called by muse, mutect2, varscan2
- CCDC150 | c.2412G>T p.Q804H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99777481; called by muse, mutect2
- CCDC3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV66558288; called by muse, mutect2, varscan2
- CCDC30 | c.442del p.T148Lfs*6 (on ENST00000340612; = p.T105Lfs*6 on NM_001080850.3) | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | catalogued as rs775731046; called by mutect2, pindel, varscan2
- CD200R1 | c.113A>G p.Y38C (on ENST00000471858 / NM_170780.3; = p.Y61C on NM_138806.4) | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.584); catalogued as COSV99867949; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CD99L2 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs781819862, COSV100692602; called by muse, mutect2, varscan2
- CDADC1 | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99212623; called by muse, mutect2
- CDH20 | c.2236C>A p.Q746K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53010838, COSV99406756; called by muse, mutect2, varscan2
- CDKL2 | c.1444T>C p.S482P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1182477130, COSV100277243; called by muse, mutect2, varscan2
- CDKL4 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101115593; called by muse, mutect2, varscan2
- CEACAM1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 62/165 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.67); catalogued as rs1199767046, COSV50734946, COSV99362673; called by muse, mutect2, varscan2
- CELSR2 | c.2229G>C p.E743D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99604974; called by muse, mutect2, varscan2
- CEP76 | c.295del p.T99Lfs*90 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as rs747064410; called by mutect2, varscan2
- CES3 | c.653del p.G218Vfs*54 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | catalogued as COSV57593378; called by mutect2, pindel, varscan2
- CHD4 | c.3292C>T p.R1098C (on ENST00000357008 / NM_001363606.2; = p.R1111C on NM_001273.5) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58909231; called by muse, mutect2, varscan2
- CHD6 | c.3251G>A p.R1084H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs764165462, COSV58557451; called by muse, mutect2, varscan2
- CHD7 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV101418561; called by muse, mutect2, varscan2
- CHORDC1 | c.663del p.D222Mfs*36 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs1361626211; called by pindel, varscan2
- CHRNA2 | c.703A>G p.N235D | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.013); catalogued as COSV99532586; called by muse, mutect2, varscan2
- CHST12 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs774912345, COSV99324724; called by muse, mutect2, varscan2
- CIT | c.5849C>A p.P1950Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV99951314; called by muse, mutect2, varscan2
- CLIC1 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV101007522, COSV101007569; called by muse, mutect2, varscan2
- CLPX | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100269503, COSV100269716; called by muse, varscan2
- CLSTN2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs528619654, COSV101515948; called by muse, mutect2, varscan2
- CLUH | c.385C>T p.R129C (on ENST00000435359; = p.R167C on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466937789, COSV101425926; called by muse, mutect2, varscan2
- CMAS | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777453073, COSV99982766; called by muse, mutect2, varscan2
- CNGB1 | c.3461A>G p.Q1154R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.63); catalogued as COSV99212377; called by muse, mutect2, varscan2
- CNNM2 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100881947; called by muse, mutect2, varscan2
- CNTN1 | c.2140G>T p.G714* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100752006; called by muse, mutect2, varscan2
- COBL | c.3503A>T p.K1168M | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474552; called by muse, mutect2, varscan2
- COL5A1 | c.4050dup p.G1351Rfs*14 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs758337699; called by mutect2, varscan2
- COL7A1 | c.4858C>T p.R1620W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs781705982, COSV100095658; called by muse, mutect2, varscan2
- COPS6 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100385224; called by muse, mutect2, varscan2
- CPSF1 | c.4216C>T p.R1406C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100450787; called by muse, mutect2
- CPXM2 | c.1722C>G p.D574E | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99583559; called by muse, mutect2
- CPZ | c.655G>A p.G219S (on ENST00000360986 / NM_001014447.3; = p.G208S on NM_003652.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139002359; called by muse, varscan2
- CSMD2 | c.7582G>T p.A2528S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV53899811; called by muse, mutect2, varscan2
- CTC1 | c.2035G>T p.G679C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV100236894; called by muse, varscan2
- CUL2 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1400970795, COSV101039326; called by muse, mutect2, varscan2
- CXCR1 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99826460; called by mutect2, varscan2
- CXCR3 | c.351G>T p.W117C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101031755; called by muse, mutect2, varscan2
- CYB561 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.166); catalogued as rs887410054, COSV100669216; called by muse, mutect2, varscan2
- DAGLB | c.1292T>G p.I431S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.033); catalogued as COSV99766267; called by muse, mutect2, varscan2
- DAP3 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100546692; called by muse, mutect2, varscan2
- DAPK1 | c.2224+2T>C p.X742_splice | Splice Site (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100802895; called by muse, mutect2
- DCTN5 | c.400T>G p.L134V | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.065); catalogued as COSV100266124; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs759023106; called by mutect2, varscan2
- DECR2 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs145686298; called by muse, mutect2, varscan2
- DEFB106B | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100128985; called by muse, varscan2
- DGAT1 | c.1253T>C p.L418P | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100184223, COSV60047248; called by muse, mutect2, varscan2
- DGKD | c.956C>G p.T319R (on ENST00000264057 / NM_152879.3; = p.T275R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99897869; called by muse, mutect2, varscan2
- DGKH | c.1859G>C p.R620P | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99819771; called by muse, mutect2, varscan2
- DHX38 | c.2876T>C p.L959P | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99194678; called by muse, mutect2, varscan2
- DLG4 | c.340A>G p.N114D (on ENST00000399506 / NM_001321075.3; = p.N157D on NM_001365.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV100264084; called by muse, mutect2, varscan2
- DLGAP1 | c.2534A>T p.K845I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234543; called by muse, mutect2, varscan2
- DLL1 | c.1642G>A p.V548M | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs568359643, COSV64538920; called by muse, mutect2
- DLL1 | c.1061G>A p.C354Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100816221; called by muse, mutect2, varscan2
- DLX2 | c.652T>G p.S218A | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99308705; called by muse, mutect2, varscan2
- DLX4 | c.319G>A p.E107K (on ENST00000240306 / NM_138281.3; = p.E35K on NM_001934.3) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs752997759, COSV53593093, COSV99537815; called by muse, mutect2, varscan2
- DMBT1 | c.7357G>A p.V2453M (on ENST00000338354 / NM_001377530.1; = p.V1696M on NM_004406.3) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs372434439; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH10 | c.3450G>T p.E1150D (on ENST00000409039; = p.E1089D on NM_207437.3) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV101292965; called by muse, mutect2, varscan2
- DNAH3 | c.2819A>G p.Y940C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99771278; called by muse, mutect2, varscan2
- DNHD1 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV99601156; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.2473G>A p.D825N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV101448026; called by muse, mutect2
- DOCK6 | c.3314A>G p.Q1105R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV99626956; called by muse, mutect2, varscan2
- DOP1B | c.2201A>G p.K734R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101215909; called by muse, mutect2, varscan2
- DPM3 | c.260G>A p.R87H (on ENST00000341298; = p.R117H on NM_018973.3) | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV100310526; called by muse, mutect2, varscan2
- DPYSL3 | c.565G>T p.G189* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100575443, COSV58325152; called by muse, mutect2, varscan2
- DPYSL4 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1378531905, COSV58307562; called by muse, mutect2, varscan2
- DSCAML1 | c.1405C>T p.R469C (on ENST00000321322; = p.R409C on NM_020693.4) | Missense Mutation (SNP) | VAF 54/112 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199669612, COSV58393000, COSV58406702; called by muse, mutect2, varscan2
- DTWD2 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758934760, COSV100407204; called by muse, mutect2, varscan2
- DTWD2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100407205, COSV58366401; called by muse, mutect2, varscan2
- DUOX1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as COSV99973634; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs772082432; called by mutect2, varscan2
- DYRK3 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV100895864; called by muse, mutect2, varscan2
- ECI2 | c.897G>T p.M299I (on ENST00000380118 / NM_206836.3; = p.M269I on NM_006117.2) | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV100326916; called by muse, mutect2, varscan2
- EHHADH | c.981C>A p.D327E | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99213411; called by muse, mutect2, varscan2
- EIF2D | c.1750_1752del p.K584del | In Frame Del (DEL) | VAF 26/154 reads (17%) | catalogued as rs1342220527; called by pindel, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ENGASE | c.1638del p.T547Pfs*14 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs759157900, COSV56136050; called by mutect2, pindel, varscan2
- ENO1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs11544519; called by muse, mutect2, varscan2
- ERBB3 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV57246828; called by muse, mutect2, varscan2
- ERCC4 | c.1315A>C p.T439P | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs1377101758, COSV61312153; called by muse, mutect2, varscan2
- ERN2 | c.2398_2400del p.K800del | In Frame Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs1164558304; called by mutect2, pindel, varscan2
- ESPL1 | c.5420T>C p.L1807P | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99229901; called by muse, mutect2, varscan2
- ESRP2 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 43/93 reads (46%) | catalogued as COSV99251550; called by muse, mutect2, varscan2
- FAM155A | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65581020; called by muse, mutect2, varscan2
- FAM186B | c.2587A>G p.S863G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99220703; called by muse, mutect2, varscan2
- FAM214A | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99958630; called by muse, mutect2, varscan2
- FAM222B | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.725); catalogued as rs753661690, COSV100368799; called by muse, mutect2, varscan2
- FAM71A | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99674958; called by muse, mutect2, varscan2
- FAT3 | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99972249; called by muse, mutect2, varscan2
- FCHSD2 | c.2134C>T p.R712* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs765405062, COSV60813906; called by muse, mutect2, varscan2
- FCRL3 | c.2137G>T p.A713S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as COSV100943615, COSV63840926; called by muse, mutect2, varscan2
- FCRL6 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.074); catalogued as COSV100220456; called by muse, mutect2, varscan2
- FGFBP1 | c.78del p.V27* | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | catalogued as rs144178676; called by mutect2, varscan2
- FLG | c.6577A>G p.T2193A | Missense Mutation (SNP) | VAF 40/408 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as COSV100912393; called by muse, mutect2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | catalogued as rs769482947; called by mutect2, varscan2
- FNDC3A | c.2204T>G p.L735R (on ENST00000492622 / NM_001079673.2; = p.L679R on NM_014923.5) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV101257021; called by muse, mutect2, varscan2
- FOXJ2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99369115; called by muse, mutect2, varscan2
- FRMD4A | c.1763T>C p.L588P | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100662712; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs1348158626; called by mutect2, varscan2
- FTSJ3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs372104659; called by muse, mutect2, varscan2
- FUT6 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs144807324; called by muse, mutect2, varscan2
- GABBR1 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs781748710, COSV100590183; called by muse, mutect2, varscan2
- GABRR1 | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as COSV101034191; called by muse, mutect2, varscan2
- GAL3ST4 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.754); catalogued as COSV99445190; called by muse, mutect2, varscan2
- GALK2 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509337; called by muse, mutect2, varscan2
- GAS2L1 | c.1839dup p.P614Afs*13 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs78929040; called by mutect2, varscan2
- GATA3 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs1415426826, COSV100651294; called by muse, mutect2, varscan2
- GBP5 | c.777A>T p.E259D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100600192; called by muse, mutect2, varscan2
- GCLC | c.1199T>C p.F400S (on ENST00000643939; = p.F398S on NM_001498.4) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99989020; called by muse, mutect2, varscan2
- GDPD2 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV100978727; called by muse, mutect2
- GFPT2 | c.1423A>G p.S475G | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV99518214; called by muse, mutect2
- GLDC | c.2296G>C p.G766R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130982, COSV100394716; called by muse, mutect2, varscan2
- GNMT | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV99770053; called by muse, mutect2, varscan2
- GP5 | c.113dup p.D39Rfs*58 | Frame Shift Ins (INS) | VAF 12/31 reads (39%) | catalogued as rs750629635; called by mutect2, pindel, varscan2
- GPATCH3 | c.777A>G p.I259M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV100658939, COSV64651952; called by muse, mutect2, varscan2
- GPC1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs775317338, COSV99883288; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 46/109 reads (42%) | catalogued as rs1416935976; called by mutect2, varscan2
- GRM8 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs553468202, COSV58817945; called by muse, mutect2, varscan2
- GRWD1 | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99474631; called by muse, mutect2
- GTF2IRD2B | c.2396C>T p.T799M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs376335386, COSV100441307; called by mutect2, varscan2
- GTF3C5 | c.218del p.P73Qfs*132 | Frame Shift Del (DEL) | VAF 5/37 reads (14%) | catalogued as COSV100565406; called by mutect2, pindel, varscan2
- H1-1 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as rs1409782839, COSV99772228; called by muse, mutect2, varscan2
- HAND2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV100854166; called by muse, mutect2
- HCK | c.637del p.R213Efs*77 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | catalogued as rs1568993585, COSV52940118; called by mutect2, pindel, varscan2
- HDAC4 | c.527A>G p.Q176R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV100614474; called by muse, mutect2, varscan2
- HDGF | c.475G>T p.G159W | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100625940; called by muse, mutect2
- HERPUD1 | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 27/71 reads (38%) | catalogued as COSV100296103; called by muse, mutect2, varscan2
- HEXD | c.26T>A p.M9K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100028105; called by muse, varscan2
- HIRA | c.64C>T p.H22Y | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54278111; called by muse, mutect2, varscan2
- HIRIP3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54230906; called by muse, mutect2, varscan2
- HMGN3 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV99245738; called by muse, mutect2
- HNRNPL | c.893G>A p.S298N | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV99670650; called by muse, mutect2, varscan2
- HNRNPM | c.834+2T>A p.X278_splice | Splice Site (SNP) | VAF 15/52 reads (29%) | catalogued as COSV100335430; called by muse, mutect2, varscan2
- HOMEZ | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as COSV100664220; called by muse, mutect2, varscan2
- HORMAD1 | c.891G>T p.E297D | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as COSV100464540; called by muse, mutect2, varscan2
- HOXB8 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV99494244; called by muse, mutect2
- HPCAL4 | c.69C>A p.S23R | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV65716060; called by muse, mutect2
- HPS6 | c.1674del p.N559Mfs*54 | Frame Shift Del (DEL) | VAF 30/77 reads (39%) | catalogued as rs764867254; called by mutect2, pindel, varscan2
- HSPA8 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as COSV99914691; called by muse, mutect2, varscan2
- HSPG2 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.388); catalogued as COSV101013021; called by mutect2, varscan2
- HTR5A | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs371035945, COSV55287169; called by muse, mutect2, varscan2
- HTR7 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99520431; called by muse, mutect2, varscan2
- HUWE1 | c.7613G>A p.R2538H | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs370630279, COSV53343620, COSV99474801; called by muse, mutect2
- IGF2R | c.3949dup p.D1317Gfs*5 | Frame Shift Ins (INS) | VAF 29/70 reads (41%) | catalogued as rs760021495; called by mutect2, varscan2
- IGFBP7 | c.498del p.K167Rfs*13 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs765398170; called by mutect2, pindel, varscan2
- IGSF11 | c.509G>A p.G170D (on ENST00000393775 / NM_001015887.3; = p.G169D on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100678045; called by muse, mutect2, varscan2
- IL17RA | c.1423G>A p.V475M | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.493); catalogued as rs762540559, COSV60051906, COSV60055791; called by muse, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 24/90 reads (27%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | catalogued as rs762875806; called by mutect2, varscan2
- IQSEC2 | c.2261G>T p.R754M (on ENST00000642864 / NM_001111125.3; = p.R549M on NM_015075.2) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100945132; called by muse, mutect2, varscan2
- ISYNA1 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99526399; called by muse, mutect2, varscan2
- ITCH | c.1177T>C p.S393P (on ENST00000262650 / NM_001257137.3; = p.S352P on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99393306; called by muse, mutect2, varscan2
- ITGA7 | c.3064C>T p.R1022C (on ENST00000555728; = p.R978C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs147664595, COSV57698947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITPR3 | c.1699T>C p.Y567H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100968212; called by muse, mutect2
- ITSN1 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759839079, COSV67157473; called by muse, mutect2, varscan2
- JADE2 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50912883, COSV99253702; called by muse, mutect2
- JAK2 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV101081336; called by muse, mutect2, varscan2
- JARID2 | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.137); catalogued as COSV100522631; called by muse, mutect2, varscan2
- JPT1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs750053454, COSV99823959; called by muse, mutect2, varscan2
- KALRN | c.8490G>T p.Q2830H (on ENST00000360013 / NM_001024660.4; = p.Q1133H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52265019, COSV99363202; called by muse, mutect2, varscan2
- KBTBD6 | c.1433A>G p.D478G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV101068918; called by muse, mutect2
- KCNA6 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs866218754, COSV99769078; called by muse, mutect2, varscan2
- KCNIP1 | c.298A>G p.T100A (on ENST00000411494 / NM_001034837.3; = p.T89A on NM_014592.4) | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1340604657, COSV100200268; called by muse, mutect2, varscan2
- KCNJ16 | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.11); catalogued as COSV99388838; called by muse, mutect2, varscan2
- KCTD2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100483407; called by muse, mutect2, varscan2
- KDM5C | c.4317G>T p.E1439D | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV100949574; called by muse, mutect2
- KHDRBS3 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs369245979, COSV63416496; called by muse, mutect2, varscan2
- KIAA1217 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs778850288, COSV100287451; called by muse, mutect2, varscan2
- KIF19 | c.2154G>A p.W718* | Nonsense Mutation (SNP) | VAF 32/59 reads (54%) | catalogued as rs1256440192, COSV100739216; called by muse, mutect2, varscan2
- KIF21A | c.3232A>G p.T1078A (on ENST00000361418 / NM_001378440.1; = p.T1065A on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.676); catalogued as COSV62779024; called by muse, mutect2, varscan2
- KIF5A | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99672885, COSV99673698; called by muse, mutect2, varscan2
- KIF5A | c.2908T>C p.Y970H | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.403); catalogued as COSV54057315, COSV99673701; called by muse, mutect2, varscan2
- KLC2 | c.1700del p.G567Afs*11 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs772643711; called by mutect2, pindel, varscan2
- KLF1 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99322525; called by muse, mutect2, varscan2
- KLHDC10 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as rs192101155, COSV100111067; called by muse, mutect2, varscan2
- KLHL12 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs1307236103, COSV100935914; called by muse, mutect2, varscan2
- KLHL34 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs555586141, COSV65280238; called by muse, varscan2
- KMO | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100844826; called by muse, mutect2, varscan2
- KMT2B | c.1657A>T p.K553* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99386315; called by muse, mutect2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KNCN | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs780686467, COSV99606382; called by muse, mutect2, varscan2
- KNDC1 | c.2033A>C p.K678T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100466518; called by muse, mutect2, varscan2
- KRBA1 | c.2087G>A p.G696D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs1228117254, COSV99753210; called by muse, mutect2, varscan2
- KRT84 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV99231078; called by muse, mutect2, varscan2
- LAMA2 | c.3372del p.K1124Nfs*15 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as rs1361925574, COSV70347760; called by mutect2, pindel, varscan2
- LANCL2 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99635250; called by muse, mutect2, varscan2
- LARP4B | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs1384562139, COSV100295791; called by muse, mutect2
- LATS2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV66875597; called by muse, mutect2, varscan2
- LIG4 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800119; called by muse, mutect2, varscan2
- LIME1 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs776251119, COSV99829519, COSV99829773; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 6/20 reads (30%) | catalogued as rs765287063; called by mutect2, varscan2
- LMF2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs764594737, COSV99327832; called by muse, mutect2, varscan2
- LNPK | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV99770538; called by muse, mutect2, varscan2
- LRIG2 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1168619888, COSV63163646; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 18/53 reads (34%) | catalogued as rs757410385; called by mutect2, varscan2
- LRRC14 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs770317927, COSV99468395; called by muse, mutect2, varscan2
- LRWD1 | c.1940T>C p.M647T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99484621; called by muse, mutect2, varscan2
- LYPD1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs908505086, COSV61415854; called by muse, mutect2, varscan2
- MACROH2A1 | c.1015G>A p.V339M (on ENST00000510038; = p.V338M on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.834); catalogued as rs149823680; called by mutect2, varscan2
- MAML3 | c.2182G>A p.G728S | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs143572204; called by muse, mutect2, varscan2
- MANEAL | c.1169C>T p.A390V (on ENST00000373045 / NM_001113482.1; = p.A168V on NM_152496.2) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs142496552; called by mutect2, varscan2
- MAOB | c.1265A>G p.Y422C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100956279; called by muse, mutect2, varscan2
- MAP2K7 | c.385G>A p.G129S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607673; called by muse, mutect2, varscan2
- MAST3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV99446442; called by muse, mutect2, varscan2
- MB21D2 | c.1180A>G p.M394V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV101165204; called by muse, mutect2, varscan2
- MCF2 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs754885951, COSV100645268; called by muse, mutect2, varscan2
- MCF2L2 | c.1714T>C p.Y572H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs779252085, COSV100194205; called by muse, mutect2, varscan2
- MEGF8 | c.6428del p.G2143Afs*20 (on ENST00000251268 / NM_001271938.2; = p.G2076Afs*20 on NM_001410.3) | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs1258909672; called by pindel, varscan2
- MEN1 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99581927; called by muse, mutect2, varscan2
- METTL4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs573099484, COSV100170788; called by muse, mutect2, varscan2
- MEX3D | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101183490; called by muse, mutect2, varscan2
- MFSD6 | c.1497T>A p.F499L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV55623116, COSV99855472; called by muse, mutect2, varscan2
- MGAT3 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs558250058, COSV57869227; called by muse, mutect2, varscan2
- MIEF1 | c.1030G>A p.A344T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs544735642, COSV100307875; called by muse, mutect2, varscan2
- MITD1 | c.194T>A p.I65N | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99175570; called by muse, mutect2, varscan2
- MITF | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.239); catalogued as COSV100106744; called by muse, mutect2, varscan2
- MKI67 | c.5587C>T p.Q1863* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100897087; called by muse, mutect2, varscan2
- MLX | c.664C>T p.H222Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.837); catalogued as COSV99519162; called by muse, mutect2, varscan2
- MMP21 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs754206831, COSV64289843; called by muse, mutect2, varscan2
- MMS22L | c.1166del p.K389Sfs*10 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV51527266; called by mutect2, pindel, varscan2
- MMS22L | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99247889; called by muse, mutect2, varscan2
- MRPL38 | c.562T>C p.Y188H | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.041); catalogued as COSV99485635; called by muse, mutect2, varscan2
- MTBP | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV100012672; called by muse, mutect2, varscan2
- MTFR1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775780841, COSV100050458; called by muse, mutect2, varscan2
- MUC5B | c.5747C>T p.T1916M | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs772902423, COSV71590678; called by muse, mutect2, varscan2
- MUC5B | c.16184C>A p.P5395H | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV101500920; called by muse, mutect2, varscan2
- MUC6 | c.4076C>T p.T1359M | Missense Mutation (SNP) | VAF 77/205 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as rs770609005, COSV101424871; called by muse, mutect2, varscan2
- MUC6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV101424872; called by muse, mutect2, varscan2
- MXRA8 | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.12); catalogued as COSV100492142; called by muse, mutect2, varscan2
- MYH9 | c.1939G>T p.G647W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53390640; called by muse, mutect2, varscan2
- MYLK | c.2820G>T p.E940D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100659800; called by muse, mutect2, varscan2
- MYO1E | c.2449G>A p.E817K | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.612); catalogued as rs200616570, COSV99896855; called by muse, mutect2, varscan2
- MYO5C | c.4956G>T p.K1652N | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99953716; called by muse, mutect2, varscan2
- MYOD1 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100000464; called by muse, mutect2, varscan2
- MYRF | c.789del p.S264Afs*8 (on ENST00000278836 / NM_001127392.3; = p.S255Afs*8 on NM_013279.4) | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | catalogued as rs769274302, COSV53895135; called by mutect2, varscan2
- N6AMT1 | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs1055160891, COSV100375123; called by muse, mutect2, varscan2
- NAPA | c.578T>C p.M193T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs897459988, COSV99645946; called by muse, mutect2, varscan2
- NARS2 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99807762; called by muse, mutect2, varscan2
- NAV2 | c.5722C>T p.R1908* (on ENST00000396087 / NM_001244963.2; = p.R1849* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs1418608328, COSV60661502; called by muse, mutect2, varscan2
- NDST1 | c.712G>C p.V238L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as COSV55785138, COSV99939141; called by muse, mutect2, varscan2
- NDUFS1 | c.11T>A p.I4K | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV99261624; called by muse, mutect2, varscan2
- NDUFS7 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99283073; called by muse, mutect2, varscan2
- NECAB3 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99865248; called by muse, mutect2, varscan2
- NEDD9 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101053452, COSV65159809; called by muse, mutect2, varscan2
- NFATC2 | c.2080A>G p.I694V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101044855; called by muse, mutect2, varscan2
- NFATC4 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99151445; called by muse, mutect2
- NFKBIE | c.1270C>T p.L424F (on ENST00000275015; = p.L285F on NM_004556.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1363944769, COSV99241502; called by muse, mutect2, varscan2
- NLRP5 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as rs1345175754, COSV66762161; called by muse, mutect2, varscan2
- NLRP8 | c.1295C>A p.S432Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52590177, COSV99406111; called by muse, mutect2
- NMRAL1 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs775780185, COSV52059474; called by muse, mutect2, varscan2
- NOD1 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs1459028958, COSV99768596; called by muse, mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NPIPB15 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs1279673931; called by muse, mutect2
- NPR3 | c.551T>C p.M184T | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99424014; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs774343392; called by mutect2, varscan2
- NRG1 | c.133G>A p.A45T (on ENST00000523534; = p.A192T on NM_013962.2) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV73061659; called by muse, varscan2
- NRXN1 | c.2612G>A p.S871N | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100455523; called by muse, mutect2, varscan2
- NRXN1 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs778031536, COSV58461473; called by muse, mutect2, varscan2
- NTHL1 | c.546G>T p.W182C (on ENST00000219066; = p.W174C on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV99526556; called by muse, mutect2
- NTN1 | c.1103G>A p.C368Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99434086; called by muse, mutect2, varscan2
- NUTM1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as rs775619864, COSV59215632; called by muse, mutect2, varscan2
- OBSCN | c.6713A>C p.D2238A | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.921); catalogued as COSV99485761; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as CD000269; called by mutect2, varscan2
- OR10A2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100225214; called by muse, mutect2, varscan2
- OR14K1 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99314924; called by muse, mutect2, varscan2
- OR2M7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs746504653, COSV58739412; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | catalogued as rs755413956; called by mutect2, varscan2
- OR5D18 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs770766899, COSV100450944; called by mutect2, varscan2
- OR6C65 | c.465del p.V158* | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs1403510488; called by pindel, varscan2
- OR6C65 | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV101110220; called by muse, mutect2, varscan2
- OR6N2 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs771450756, COSV100210153, COSV100210556; called by muse, mutect2, varscan2
- OXER1 | c.231dup p.S78Vfs*61 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | catalogued as rs753912794; called by mutect2, varscan2
- PABPC1L | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99408265; called by muse, mutect2, varscan2
- PABPC3 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs746078288, COSV55797266; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PAGE2B | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100894315; called by muse, mutect2, varscan2
- PAK5 | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100781775; called by muse, mutect2, varscan2
- PANK2 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as COSV100262542; called by muse, mutect2
- PANK4 | c.1576-1G>T p.X526_splice | Splice Site (SNP) | VAF 10/57 reads (18%) | catalogued as COSV101022587; called by muse, mutect2, varscan2
- PAPPA | c.4292G>A p.G1431D | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100075675; called by muse, mutect2, varscan2
- PAPPA2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746410678, COSV62775917; called by muse, mutect2, varscan2
- PARP11 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.202); catalogued as rs746746559, COSV99959328; called by muse, mutect2, varscan2
- PARP4 | c.5065C>T p.R1689W | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756987701; called by muse, varscan2
- PBRM1 | c.835del p.I279Yfs*4 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | catalogued as rs771618422; called by mutect2, pindel, varscan2
- PBX2 | c.50del p.G17Afs*5 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs773143486; called by mutect2, varscan2
- PBXIP1 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as COSV100870139; called by muse, mutect2, varscan2
- PCDHA3 | c.1724G>A p.G575D | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV100793839; called by muse, mutect2, varscan2
- PCDHA5 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.036); catalogued as rs782698382, COSV65350502; called by muse, mutect2, varscan2
- PCDHAC1 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV53838885, COSV99170185; called by muse, mutect2, varscan2
- PCDHAC2 | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as COSV99163580; called by muse, mutect2
- PCDHB1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as COSV60629475; called by muse, mutect2
- PDGFB | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs758693929, COSV100483622; called by muse, mutect2, varscan2
- PDS5B | c.1180A>T p.R394* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs750827034, COSV59724936; called by muse, mutect2, varscan2
- PDZD7 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV100931724; called by muse, mutect2, varscan2
- PFAS | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100119208; called by muse, mutect2, varscan2
- PHLPP1 | c.5066A>C p.Q1689P | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV99409547; called by muse, mutect2, varscan2
- PHRF1 | c.123C>G p.D41E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV99213820; called by muse, mutect2, varscan2
- PIK3R3 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV99423130; called by muse, mutect2, varscan2
- PIWIL2 | c.2393del p.K798Sfs*5 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | catalogued as COSV63249731; called by mutect2, pindel, varscan2
- PJA2 | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs780645154, COSV100754576; called by muse, mutect2, varscan2
- PKIA | c.35T>G p.I12S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100775249; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 16/46 reads (35%) | catalogued as rs747170999; called by pindel, varscan2
- PLA2G12A | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs368449766; called by muse, mutect2, varscan2
- PLCB3 | c.1571A>C p.E524A | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.212); catalogued as COSV99657840; called by muse, mutect2, varscan2
- PLEKHH2 | c.4469C>A p.P1490H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99175270; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs778393033; called by mutect2, pindel, varscan2
- PLEKHO2 | c.1131dup p.W378Lfs*57 | Frame Shift Ins (INS) | VAF 14/40 reads (35%) | catalogued as rs1445368316; called by mutect2, pindel, varscan2
- PLSCR3 | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100248033; called by muse, mutect2, varscan2
- PLXNA1 | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV99304339; called by muse, varscan2
- PLXNA3 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs200170081, COSV63753547; called by muse, mutect2, varscan2
- PLXNB2 | c.5042C>T p.T1681M | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867242805, COSV100834360; called by muse, mutect2, varscan2
- PLXNB2 | c.2296G>A p.D766N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1442577954, COSV63779908; called by muse, mutect2, varscan2
- PNLIPRP3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs565944175, COSV100982661; called by muse, mutect2, varscan2
- POLG | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV99175134; called by muse, mutect2
- POLRMT | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1324801906, COSV101646109; called by muse, mutect2, varscan2
- POMT2 | c.1864G>T p.G622W | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99836760; called by muse, mutect2
- PPARG | c.1424C>T p.T475M (on ENST00000287820 / NM_015869.5; = p.T445M on NM_005037.7) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1479145908, COSV55141227; called by muse, mutect2, varscan2
- PPARGC1A | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs539338812, COSV53524913; called by muse, mutect2, varscan2
- PPFIA2 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV100335607; called by muse, mutect2
- PPP1R13L | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62908675; called by muse, mutect2, varscan2
- PPT2 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV61354420; called by muse, mutect2, varscan2
- PRAF2 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV59875369; called by muse, mutect2, varscan2
- PRAG1 | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771709111, COSV100423002; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 23/108 reads (21%) | catalogued as rs778683789; called by mutect2, varscan2
- PREX1 | c.2702G>A p.C901Y | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100906902; called by muse, mutect2, varscan2
- PRKACA | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100432374, COSV58068853; called by muse, mutect2, varscan2
- PRKCE | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1363074103, COSV100079808; called by muse, mutect2
- PROM2 | c.1058G>T p.S353I | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs1406393082, COSV100469118; called by muse, mutect2
- PRPF3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100255189; called by muse, mutect2, varscan2
- PRPF38A | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99933487; called by muse, mutect2
- PRR19 | c.870G>T p.W290C | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV100004193; called by muse, mutect2, varscan2
- PRSS16 | c.1021A>G p.S341G | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100042053; called by muse, mutect2, varscan2
- PSD3 | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as COSV100497388; called by muse, mutect2, varscan2
- PTCH1 | c.3921dup p.R1308Qfs*17 | Frame Shift Ins (INS) | VAF 30/78 reads (38%) | catalogued as rs761353734; called by mutect2, varscan2
- PTMA | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100398511; called by muse, mutect2, varscan2
- QRICH2 | c.4477G>T p.G1493W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99429850; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RANBP2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 118/293 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs770986482, COSV99313571; called by muse, mutect2, varscan2
- RAP1GAP2 | c.903G>T p.Q301H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.765); catalogued as COSV54588936, COSV99624661; called by muse, mutect2, varscan2
- RAPH1 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052082; called by muse, mutect2, varscan2
- RASAL1 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.054); catalogued as COSV99922217; called by muse, mutect2
- RASGRF1 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV101369792; called by muse, mutect2, varscan2
- RASSF5 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs201563198, COSV100456349, COSV58798040; called by muse, varscan2
- RBBP6 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.799); catalogued as rs756879107, COSV60506852; called by muse, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs781825075; called by mutect2, varscan2
- RBM25 | c.1969C>A p.Q657K | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.87); PolyPhen benign (0.177); catalogued as COSV99999214; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs762006287; called by mutect2, varscan2
- RELN | c.9200C>A p.T3067N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV100635130; called by muse, mutect2
- RELN | c.7526A>G p.D2509G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV59020441; called by muse, mutect2
- RFNG | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100136174; called by muse, mutect2
- RGS7 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100471744; called by muse, mutect2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs746684945; called by mutect2, varscan2
- RIMS1 | c.4009G>A p.A1337T | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV99331355; called by muse, mutect2, varscan2
- RND2 | c.103-2A>G p.X35_splice | Splice Site (SNP) | VAF 28/87 reads (32%) | catalogued as COSV99870110; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 45/71 reads (63%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROS1 | c.2192T>G p.L731R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100877844; called by muse, mutect2, varscan2
- RP1 | c.5347G>A p.V1783I | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV55127264; called by muse, mutect2, varscan2
- RPL10L | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs1303053099, COSV100022706; called by muse, mutect2, varscan2
- RSPH10B2 | c.488T>C p.M163T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV99786452; called by mutect2, varscan2
- RTN2 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV99839319; called by muse, mutect2
- RUSC1 | c.1543G>A p.G515S (on ENST00000368352 / NM_001105203.2; = p.G46S on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1310927910, COSV99430399; called by muse, mutect2
- SAP130 | c.2701C>T p.R901C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99385491; called by muse, mutect2, varscan2
- SCAMP2 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1360733410, COSV99174022; called by muse, mutect2, varscan2
- SCAP | c.2068T>C p.W690R | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as COSV99653356; called by muse, mutect2
- SCN11A | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100182890; called by muse, mutect2, varscan2
- SCN9A | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.309); catalogued as COSV57598772, COSV57621631; called by muse, mutect2, varscan2
- SDK1 | c.4321G>A p.D1441N | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.241); catalogued as rs368279674; called by muse, mutect2, varscan2
- SEC14L5 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs756053430, COSV99229510; called by muse, mutect2, varscan2
- SEMA4F | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.651); catalogued as COSV100336174; called by muse, mutect2, varscan2
- SEMA6A | c.2637dup p.K880Qfs*36 | Frame Shift Ins (INS) | VAF 25/94 reads (27%) | catalogued as rs749631581; called by mutect2, pindel, varscan2
- SENP3 | c.84G>T p.R28S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99548041; called by muse, mutect2, varscan2
- SERPINB7 | c.916G>T p.D306Y | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100320352; called by muse, mutect2
- SETBP1 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV99955391; called by muse, mutect2, varscan2
- SFI1 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101192331; called by muse, mutect2, varscan2
- SHC1 | c.92del p.P31Rfs*35 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs752843778; called by mutect2, pindel, varscan2
- SHE | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.537); catalogued as rs755012416, COSV100496257; called by muse, mutect2, varscan2
- SHKBP1 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs757621526, COSV99399465; called by muse, mutect2, varscan2
- SHPRH | c.483G>T p.E161D | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV99262682; called by muse, mutect2, varscan2
- SIX3 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99578621; called by muse, mutect2, varscan2
- SLC10A3 | c.1337C>A p.S446Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54836708, COSV99682278; called by muse, mutect2
- SLC12A4 | c.2311C>T p.R771W | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs756470637, COSV99863369; called by muse, mutect2, varscan2
- SLC12A9 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99308322; called by muse, varscan2
- SLC16A11 | c.709A>G p.S237G (on ENST00000308009; = p.S213G on NM_153357.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100338778; called by mutect2, varscan2
- SLC16A6 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs781955671, COSV100517444; called by muse, mutect2, varscan2
- SLC17A8 | c.1180T>C p.C394R | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs758711149, COSV100035944; called by muse, mutect2, varscan2
- SLC22A5 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as rs754008420, COSV99810260; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC23A2 | c.1688G>A p.C563Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV100595253; called by muse, mutect2, varscan2
- SLC30A3 | c.1159del p.Q387Kfs*78 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs747206800; called by mutect2, pindel, varscan2
- SLC38A6 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99712427; called by muse, mutect2, varscan2
- SLC39A10 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100660791; called by muse, mutect2, varscan2
- SLC39A7 | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.105); catalogued as COSV100807898; called by muse, mutect2
- SLC44A3 | c.1870del p.R624Gfs*5 (on ENST00000271227 / NM_001114106.3; = p.R576Gfs*5 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 7/17 reads (41%) | catalogued as COSV54728395; called by mutect2, pindel, varscan2
- SLC6A17 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs189456665, COSV58991953; called by muse, mutect2, varscan2
- SLC6A5 | c.2191A>C p.I731L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100117242; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs760667210; called by mutect2, varscan2
- SMCR8 | c.1879C>A p.R627S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100329363, COSV58180209; called by muse, mutect2
- SMTN | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.399); catalogued as COSV100295038; called by muse, mutect2, varscan2
- SNAP25 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV54771039; called by muse, mutect2, varscan2
- SORBS2 | c.1949A>G p.H650R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs562339021, COSV52994457; called by muse, mutect2
- SOX13 | c.856C>A p.L286M | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as COSV99690086; called by muse, mutect2, varscan2
- SPATA7 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99248510; called by muse, mutect2, varscan2
- SPPL2B | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs966841418, COSV101194704; called by muse, mutect2, varscan2
- SRGAP1 | c.2816C>T p.T939M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.047); catalogued as rs1186421658, COSV61900862; called by muse, mutect2
- SRPK1 | c.1460del p.N487Mfs*7 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | catalogued as rs1561978130; called by mutect2, pindel, varscan2
- ST8SIA4 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | PolyPhen possibly damaging (0.59); catalogued as COSV99185630; called by muse, mutect2, varscan2
- STARD8 | c.2618del p.P873Qfs*28 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as rs761897392; called by mutect2, pindel, varscan2
- STK40 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs767722663, COSV63734773, COSV63735233; called by muse, mutect2, varscan2
- SULF1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.52); catalogued as rs769376901, COSV52692331; called by muse, mutect2, varscan2
- SUPT5H | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV100782184; called by muse, mutect2, varscan2
- SUPT5H | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.418); catalogued as COSV100782185; called by muse, mutect2
- SUPT5H | c.1906T>C p.F636L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.562); catalogued as COSV100782186; called by muse, mutect2, varscan2
- SVIL | c.2920G>A p.A974T (on ENST00000355867 / NM_021738.3; = p.A548T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs757847426, COSV100881621; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs753462162; called by mutect2, varscan2
- SYNE3 | c.2315A>G p.N772S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.186); catalogued as rs978203906, COSV100516662; called by muse, mutect2, varscan2
- SYNPO | c.857T>G p.L286R (on ENST00000394243 / NM_001166208.2; = p.L42R on NM_007286.6) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776616689, COSV100302498; called by muse, mutect2, varscan2
- SYNPO2L | c.1289del p.P430Qfs*15 (on ENST00000394810 / NM_001114133.3; = p.P206Qfs*15 on NM_024875.5) | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | catalogued as rs1302970786; called by mutect2, pindel, varscan2
- TAF1 | c.1932del p.F644Lfs*27 (on ENST00000373790 / NM_138923.4; = p.F665Lfs*27 on NM_004606.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 40/116 reads (34%) | catalogued as COSV52129377; called by mutect2, pindel, varscan2
- TBC1D14 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as COSV101299081; called by muse, mutect2, varscan2
- TBC1D25 | c.1347del p.S450Afs*22 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | catalogued as rs1556985760; called by mutect2, pindel, varscan2
- TCEAL3 | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99685365; called by muse, mutect2
- TCF20 | c.3446T>C p.V1149A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV100167082; called by muse, mutect2, varscan2
- TCHH | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1206765822, COSV100915597, COSV64278231; called by muse, mutect2
- TCTN1 | c.1246A>G p.T416A (on ENST00000551590 / NM_001173975.3; = p.T402A on NM_024549.6) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV100886278; called by muse, mutect2, varscan2
- TEAD1 | c.929G>T p.S310I | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100533045; called by muse, mutect2
- TENM3 | c.6742T>G p.F2248V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV101305550; called by muse, mutect2, varscan2
- TENM4 | c.2147A>G p.D716G | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99580565; called by muse, varscan2
- TENT5A | c.1205C>G p.T402S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV100199216; called by muse, mutect2, varscan2
- TESK2 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); catalogued as rs1159495047, COSV100517821; called by muse, mutect2, varscan2
- TFE3 | c.1579G>T p.E527* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100252923; called by muse, mutect2, varscan2
- TGFB3 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53169804; called by muse, mutect2, varscan2
- TGFBRAP1 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs756815583, COSV51513748; called by muse, mutect2, varscan2
- TGM1 | c.1228T>G p.S410A | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99253298; called by muse, mutect2, varscan2
- THAP3 | c.188G>A p.C63Y | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs969963825, COSV99276031; called by muse, mutect2, varscan2
- TIRAP | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV101201683; called by muse, mutect2
- TLL2 | c.1507G>T p.G503* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100780380; called by muse, mutect2, varscan2
- TLR9 | c.2642G>A p.S881N | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.419); catalogued as COSV100645778; called by muse, mutect2, varscan2
- TM9SF2 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.395); catalogued as COSV100899794; called by muse, mutect2, varscan2
- TMEM120B | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.833); catalogued as rs759084901, COSV61182698; called by muse, mutect2, varscan2
- TMEM132E | c.2477A>G p.Y826C (on ENST00000321639; = p.Y916C on NM_001304438.2) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100396886; called by mutect2, varscan2
- TMEM169 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); catalogued as COSV99824691; called by muse, mutect2, varscan2
- TMEM171 | c.218C>G p.A73G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55130124, COSV55132300; called by muse, mutect2, varscan2
- TMEM94 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs143448418, COSV58599709; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TP53BP2 | c.2687G>A p.R896H (on ENST00000343537 / NM_001031685.3; = p.R767H on NM_005426.2) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.488); catalogued as rs1287062253, COSV100636865; called by mutect2, varscan2
- TPX2 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs889664730, COSV100302180; called by muse, mutect2, varscan2
- TRAF3IP3 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as rs766870528, COSV99163070; called by muse, mutect2, varscan2
- TRIM48 | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV101338368, COSV101338378; called by muse, mutect2, varscan2
- TRPV3 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763160386, COSV100028247; called by muse, mutect2, varscan2
- TRPV4 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99925169; called by muse, mutect2, varscan2
- TRRAP | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs782751174, COSV100723184; called by muse, mutect2, varscan2
- TSHZ1 | c.836A>G p.D279G (on ENST00000580243 / NM_001308210.2; = p.D234G on NM_005786.6) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV100433976; called by muse, mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs1193207010; called by mutect2, varscan2
- TTC21A | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100087784; called by muse, mutect2, varscan2
- TTC24 | c.908A>G p.H303R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100964385; called by muse, mutect2
- TTLL9 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1375690327, COSV60592400; called by muse, mutect2, varscan2
- TUBGCP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.93); catalogued as rs1295994236; called by muse, mutect2, varscan2
- TYW1 | c.247dup p.Y83Lfs*17 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs952169120; called by mutect2, pindel, varscan2
- TYW5 | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | catalogued as rs375238758; called by muse, mutect2, varscan2
- UBE4A | c.2384C>T p.A795V (on ENST00000252108 / NM_001204077.2; = p.A802V on NM_004788.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99348721; called by muse, varscan2
- UBE4B | c.1747C>T p.R583W (on ENST00000343090 / NM_001105562.3; = p.R454W on NM_006048.5) | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53533284; called by muse, mutect2, varscan2
- UCHL1 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99449404; called by muse, mutect2, varscan2
- UFSP2 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as COSV99249402; called by muse, mutect2, varscan2
- UMODL1 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs1378469376, COSV101253575; called by muse, mutect2, varscan2
- UNC5C | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.935); catalogued as COSV71658968, COSV71659190; called by muse, mutect2, varscan2
- UNC80 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99781417; called by muse, mutect2, varscan2
- UQCRC1 | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs772442813, COSV99179028; called by muse, mutect2, varscan2
- USP26 | c.1461del p.F487Lfs*40 | Frame Shift Del (DEL) | VAF 9/13 reads (69%) | catalogued as rs761320003; called by mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs764735138; called by mutect2, varscan2
- USP48 | c.1894+2T>C p.X632_splice | Splice Site (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100380315; called by muse, mutect2, varscan2
- VAMP8 | c.115del p.E39Kfs*36 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs774807701, COSV55705928, COSV99809221; called by mutect2, pindel, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | catalogued as rs756863093; called by mutect2, varscan2
- VWC2 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100514921; called by muse, mutect2, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs756173793; called by mutect2, varscan2
- WASHC2C | c.1547del p.K516Rfs*41 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | catalogued as rs782259587; called by mutect2, varscan2
- WDR70 | c.1184C>A p.S395Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99460856; called by muse, mutect2, varscan2
- WNK1 | c.3761C>T p.A1254V (on ENST00000315939 / NM_018979.4; = p.A1007V on NM_014823.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60029087; called by muse, mutect2, varscan2
- WNT16 | c.500dup p.C168Lfs*4 (on ENST00000222462 / NM_057168.2; = p.C158Lfs*4 on NM_016087.2) | Frame Shift Ins (INS) | VAF 8/26 reads (31%) | catalogued as rs771899177; called by mutect2, varscan2
- YBX1 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100172260; called by muse, mutect2, varscan2
- YIPF7 | c.82T>G p.L28V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV60657676; called by muse, mutect2, varscan2
- ZBTB14 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100813485; called by muse, mutect2
- ZC3H12B | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100162195; called by muse, mutect2, varscan2
- ZC3H13 | c.2988dup p.G997Rfs*8 | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | catalogued as rs1427142993; called by mutect2, varscan2
- ZFP57 | c.1588G>C p.V530L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.023); catalogued as COSV100971996; called by muse, mutect2, varscan2
- ZIM3 | c.897del p.V300Ffs*24 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV54143143; called by mutect2, pindel, varscan2
- ZMYND19 | c.236dup p.V80Rfs*34 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs753541275; called by mutect2, varscan2
- ZNF207 | c.320del p.K107Rfs*57 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as rs748924817, COSV58300448, COSV58302045; called by mutect2, varscan2
- ZNF281 | c.2066G>A p.G689D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.084); catalogued as COSV99664587; called by muse, varscan2
- ZNF281 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 60/87 reads (69%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99664467; called by muse, varscan2
- ZNF365 | c.1196del p.K399Sfs*6 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs751774089; called by mutect2, varscan2
- ZNF429 | c.1354C>A p.P452T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as COSV100642063; called by muse, mutect2, varscan2
- ZNF446 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1423309849, COSV52180235; called by muse, mutect2, varscan2
- ZNF524 | c.174del p.K59Sfs*14 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as rs750719825; called by mutect2, varscan2
- ZNF609 | c.4081C>T p.R1361C | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1381024670, COSV100441151; called by muse, mutect2, varscan2
- ZNF610 | c.942A>C p.K314N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100017085; called by muse, mutect2, varscan2
- ZNF610 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100017086; called by muse, mutect2, varscan2
- ZNF85 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs150048393, COSV60213393; called by muse, mutect2, varscan2
- ZNF862 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs753667364, COSV56223085, COSV56225423; called by mutect2, varscan2
- AATF | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ACAT1 | c.167dup p.L56Ffs*11 | Frame Shift Ins (INS) | VAF 37/111 reads (33%) | called by mutect2, pindel, varscan2
- ADRA1D | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- AGBL2 | c.2252del p.K751Rfs*19 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, varscan2
- ALOX5 | c.522del p.G175Efs*6 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- ARAP3 | c.2090del p.P697Lfs*44 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- ARFGAP1 | c.883del p.S295Rfs*30 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- BBS12 | c.2129del p.L710Cfs*6 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- BMP3 | c.1073del p.K358Rfs*20 | Frame Shift Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, pindel, varscan2
- BRWD1 | c.6926dup p.L2309Ffs*19 | Frame Shift Ins (INS) | VAF 9/24 reads (38%) | called by mutect2, varscan2
- C9orf50 | c.771dup p.S258Lfs*6 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- CCND1 | c.866_877dup p.D289_D292dup | In Frame Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, varscan2
- CD320 | c.551del p.P184Lfs*2 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel, varscan2
- CD34 | c.806del p.K269Sfs*5 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- CETP | c.790del p.L264Sfs*30 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- CFAP47 | c.1563del p.A522Lfs*7 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | called by mutect2, pindel, varscan2
- CHD3 | c.4733del p.N1578Tfs*40 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- CHERP | c.1849del p.H617Mfs*38 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- CNNM1 | c.2577G>T p.M859I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); called by muse, mutect2
- COL4A1 | c.4619del p.N1540Tfs*2 | Frame Shift Del (DEL) | VAF 34/101 reads (34%) | called by mutect2, pindel, varscan2
- CPED1 | c.1208del p.L403* | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10978del p.T3660Hfs*41 (on ENST00000297405 / NM_001363185.1; = p.T3491Hfs*41 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- DDX52 | c.915del p.G306Efs*4 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- DENND1A | c.1318del p.M440Wfs*3 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | called by mutect2, pindel, varscan2
- DGCR2 | c.144del p.W49Gfs*21 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- DLC1 | c.2487del p.S830Rfs*7 (on ENST00000276297 / NM_001348081.2; = p.S393Rfs*7 on NM_006094.5) | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel, varscan2
- DLG2 | c.326del p.N109Mfs*66 (on ENST00000650630 / NM_001351274.2; = p.N72Mfs*66 on NM_001142699.3) | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- DNAH7 | c.8194del p.I2732Lfs*15 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- DNTT | c.366del p.K122Nfs*6 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- EDEM3 | c.572del p.L191Yfs*17 | Frame Shift Del (DEL) | VAF 13/139 reads (9%) | called by mutect2, pindel
- EIF2S3 | c.740del p.P247Qfs*32 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- EPPIN | c.204del p.K68Nfs*3 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | called by mutect2, pindel, varscan2
- FOXN2 | c.1134del p.Q380Sfs*35 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- FXR1 | c.370_371del p.N124Yfs*4 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- GNL3 | c.71del p.K24Rfs*9 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | called by mutect2, pindel, varscan2
- GPC3 | c.240del p.K80Nfs*4 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- HACD1 | c.303del p.G102Efs*25 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, varscan2
- HACD1 | c.258-3_299delinsAGGTGGTTGGTTCTAGCTATTGCCATGGTACGTTTTTATATGG p.X86_splice | Splice Site (DEL) | VAF 4/42 reads (10%) | called by pindel, varscan2*
- HPS1 | c.2028dup p.T677Hfs*2 | Frame Shift Ins (INS) | VAF 24/76 reads (32%) | called by mutect2, pindel, varscan2
- HS6ST1 | c.187del p.H63Tfs*21 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- HTR2C | c.1043del p.K348Sfs*3 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- HTT | c.2096del p.N699Mfs*9 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.1018G>T p.G340C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV3-15 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAL | c.2668del p.D890Tfs*9 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- ITPR3 | c.5902G>T p.D1968Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- KCNQ2 | c.856del p.Q286Rfs*33 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | called by mutect2, pindel, varscan2
- MAMDC4 | c.3029del p.P1010Lfs*60 (on ENST00000445819; = p.P931Lfs*60 on NM_206920.3) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- MYBL2 | c.113_114+1del | In Frame Del (DEL) | VAF 10/26 reads (38%) | called by pindel, varscan2
- NAV1 | c.308del p.K103Sfs*20 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- NCOR2 | c.4971del p.N1658Tfs*53 | Frame Shift Del (DEL) | VAF 48/131 reads (37%) | called by mutect2, pindel, varscan2
- NDRG1 | c.1108dup p.A370Gfs*62 | Frame Shift Ins (INS) | VAF 5/44 reads (11%) | called by mutect2, pindel
- NNT | c.645del p.F215Lfs*17 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- NOX5 | c.1407del p.H470Tfs*10 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- NPAS1 | c.714del p.S239Pfs*13 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- PFKFB2 | c.85_85+2del | In Frame Del (DEL) | VAF 7/59 reads (12%) | called by pindel, varscan2
- PLEKHA5 | c.1178dup p.N393Kfs*27 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel
- PLEKHA6 | c.982del p.V328Yfs*172 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- PLXNC1 | c.3405del p.K1135Nfs*27 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- PPFIA3 | c.1185dup p.E396* | Frame Shift Ins (INS) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.62G>T p.R21M | Missense Mutation (SNP) | VAF 57/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PREX2 | c.3637del p.R1213Gfs*31 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by pindel, varscan2
- PRPF40A | c.383del p.P128Lfs*13 | Frame Shift Del (DEL) | VAF 5/14 reads (36%) | called by mutect2, varscan2
- PSMA7 | c.377del p.P126Rfs*36 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- PTBP1 | c.931dup p.L311Pfs*53 (on ENST00000349038 / NM_031991.4; = p.L337Pfs*53 on NM_002819.5) | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- PTK7 | c.204dup p.G69Wfs*38 | Frame Shift Ins (INS) | VAF 56/147 reads (38%) | called by mutect2, pindel, varscan2
- PTMA | c.117+4_117+7del p.X39_splice | Splice Site (DEL) | VAF 19/43 reads (44%) | called by mutect2, pindel, varscan2
- RAE1 | c.1052del p.N351Ifs*12 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, varscan2
- RALGAPA2 | c.4883del p.N1628Ifs*5 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel
- SAMD3 | c.233del p.K78Rfs*42 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- SCAF4 | c.2798del p.G933Vfs*151 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- SHANK1 | c.5421del p.T1808Rfs*11 | Frame Shift Del (DEL) | VAF 7/13 reads (54%) | called by mutect2, varscan2
- SLC47A2 | c.180del p.H61Tfs*10 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- SLC5A2 | c.632del p.G211Afs*30 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, varscan2
- SOGA1 | c.3701del p.P1234Qfs*108 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.907T>C p.S303P | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by mutect2, varscan2
- SPRED1 | c.234del p.D79Tfs*42 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- SSBP3 | c.146del p.N49Tfs*95 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | called by mutect2, pindel, varscan2
- STAT3 | c.2185del p.R729Afs*3 (on ENST00000264657 / NM_001369512.1; = p.R728Afs*3 on NM_003150.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- SUCLA2 | c.1342del p.I448Yfs*15 (on ENST00000643023; = p.I427Yfs*15 on NM_003850.3) | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- SUPT5H | c.201del p.K68Rfs*33 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- SUV39H2 | c.1028del p.F343Sfs*12 (on ENST00000354919 / NM_001193424.2; = p.F283Sfs*12 on NM_024670.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- SVEP1 | c.8630del p.G2877Efs*25 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- SYCP2 | c.1073del p.N358Ifs*3 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- TEX2 | c.2497del p.W833Gfs*4 (on ENST00000583097 / NM_001288733.2; = p.W840Gfs*4 on NM_018469.5) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- TIAL1 | c.273dup p.D92Rfs*31 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- TPTE | c.637dup p.R213Kfs*4 (on ENST00000618007 / NM_199261.4; = p.R195Kfs*4 on NM_199259.4) | Frame Shift Ins (INS) | VAF 20/108 reads (19%) | called by mutect2, pindel, varscan2
- TRBV5-1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- TRERF1 | c.3116del p.G1039Afs*5 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by pindel, varscan2
- TSPAN33 | c.458dup p.F154Vfs*2 | Frame Shift Ins (INS) | VAF 21/52 reads (40%) | called by mutect2, pindel, varscan2
- USP12 | c.351del p.F117Lfs*13 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- UTP20 | c.6606del p.K2202Nfs*27 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- XAB2 | c.1709del p.G570Afs*200 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.4951_4952del p.T1651Afs*10 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ABCA2 | c.3750G>A p.T1250= (on ENST00000614293; = p.T1220= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs764350245, COSV55799244; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCA5 | c.3141T>C p.H1047= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV101201314; called by muse, mutect2, varscan2
- ABCB9 | c.2151C>T p.R717= (on ENST00000280560 / NM_019625.4; = p.R674= on NM_019624.3) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs770106220, COSV54890507; called by muse, mutect2, varscan2
- ABI3 | c.180C>T p.S60= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs769567993, COSV56799598, COSV56800321; called by muse, mutect2, varscan2
- ABTB2 | c.1572G>A p.T524= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs375692610; called by muse, mutect2, varscan2
- ACSM1 | c.315C>A p.T105= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV54640301, COSV99532365; called by muse, mutect2
- ACTN1 | c.2463C>T p.A821= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs774599678, COSV51995693; called by muse, mutect2, varscan2
- ADAM21 | c.1863T>C p.H621= | Silent (SNP) | VAF 4/90 reads (4%) | catalogued as rs1201469588; called by muse, mutect2
- ADAMTS15 | c.1725C>T p.S575= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs776200888, COSV54507565; called by muse, mutect2, varscan2
- ADCK5 | c.726C>A p.I242= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV100450786; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1069C>T p.L357= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100417045; called by muse, mutect2, varscan2
- AFG1L | c.1131G>A p.P377= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs770762851, COSV64558321; called by muse, mutect2, varscan2
- AKAP9 | c.3027A>T p.V1009= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100663339; called by muse, mutect2, varscan2
- ALDH16A1 | c.2392C>T p.L798= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99201375; called by muse, mutect2
- ALDH3B1 | c.1188C>A p.T396= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99142126; called by muse, mutect2, varscan2
- ALG11 | c.1455A>G p.S485= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV101584411; called by muse, mutect2, varscan2
- ANO8 | c.3207G>A p.A1069= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs778773714, COSV99345061; called by muse, mutect2, varscan2
- AQR | c.3714C>T p.R1238= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs371817508; called by muse, mutect2, varscan2
- ARFGEF2 | c.330T>C p.P110= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100904546; called by muse, mutect2
- ARID1B | c.1671G>A p.R557= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV99273112; called by muse, mutect2, varscan2
- ATG2B | c.1086C>T p.D362= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs377727532; called by muse, mutect2, varscan2
- ATP2A1 | c.1788A>G p.V596= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV62869074; called by muse, mutect2, varscan2
- ATP2B3 | c.2643C>T p.A881= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as rs781965639, COSV99686209; called by muse, mutect2
- C17orf64 | c.486C>T p.D162= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99293713; called by muse, mutect2, varscan2
- C1D | c.345A>G p.S115= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100878280; called by muse, mutect2, varscan2
- C1QTNF8 | c.561G>A p.R187= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100116379; called by muse, mutect2
- CACNA1C | c.6213C>T p.P2071= (on ENST00000399634 / NM_001167625.1; = p.P2000= on NM_000719.7) | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs772160508, COSV59749771, COSV59750315; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA2D4 | c.3099C>T p.C1033= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs767020808, COSV54956763, COSV54956908; called by muse, mutect2, varscan2
- CCDC113 | c.600G>A p.R200= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV54685716, COSV99541287; called by muse, mutect2, varscan2
- CCT2 | c.900T>C p.P300= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100167854; called by muse, mutect2, varscan2
- CDS1 | c.132T>C p.D44= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV55687754; called by muse, mutect2, varscan2
- CFAP74 | c.4269C>T p.S1423= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs760405325; called by muse, mutect2, varscan2
- CHD3 | c.3210A>T p.R1070= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100391837; called by muse, mutect2, varscan2
- CLDN18 | c.117C>T p.P39= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs1484107463, COSV99480529, COSV99481067; called by muse, mutect2, varscan2
- CNNM2 | c.2142C>T p.G714= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1218566915, COSV64002222; called by muse, mutect2, varscan2
- COL9A2 | c.1119G>A p.G373= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as COSV101028829; called by muse, mutect2, varscan2
- CPT1C | c.1998G>A p.L666= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs753392562, COSV99773750; called by mutect2, varscan2
- CTSD | c.1170C>T p.I390= | Silent (SNP) | VAF 18/132 reads (14%) | catalogued as rs370985523; called by muse, mutect2, varscan2
- CUBN | c.4812C>T p.G1604= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV100913726; called by muse, mutect2, varscan2
- CUL1 | c.882C>T p.V294= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100296984; called by muse, mutect2, varscan2
- CYP4F12 | c.1095C>T p.R365= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs771042085, COSV61173726; called by muse, mutect2, varscan2
- DCHS1 | c.2589G>A p.L863= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100202711; called by muse, mutect2, varscan2
- DENND4A | c.1077A>G p.P359= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV101475461; called by muse, mutect2, varscan2
- DIDO1 | c.549G>A p.G183= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs1335504986, COSV99827481; called by muse, mutect2, varscan2
- DIP2C | c.3159G>A p.V1053= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs1274120700, COSV99794093; called by muse, mutect2, varscan2
- DNAH10 | c.309G>A p.V103= (on ENST00000409039; = p.V42= on NM_207437.3) | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1263360171, COSV101292963; called by muse, mutect2, varscan2
- DTWD1 | c.345A>T p.A115= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99233810; called by muse, mutect2, varscan2
- DYRK2 | c.93G>C p.P31= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100165169, COSV100165423; called by muse, mutect2, varscan2
- E2F8 | c.2280T>C p.P760= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100001820; called by muse, mutect2, varscan2
- ECE1 | c.792G>A p.S264= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs199920950, COSV99942536; called by muse, mutect2, varscan2
- ECSIT | c.1164C>T p.P388= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as rs1200772303, COSV99369315; called by muse, mutect2, varscan2
- EFTUD2 | c.1914C>T p.D638= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV101274563; called by muse, mutect2, varscan2
- ELK1 | c.69C>A p.I23= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV99902416; called by muse, mutect2, varscan2
- EPB41L4B | c.1158C>T p.R386= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV101000599; called by muse, mutect2, varscan2
- EVC | c.1921C>T p.L641= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV53835258; called by muse, mutect2
- FBLN1 | c.1827C>T p.F609= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as rs761267107, COSV100591699; called by muse, mutect2
- FGD1 | c.1222C>A p.R408= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV100911282, COSV64309532; called by muse, mutect2, varscan2
- FLG | c.9781A>C p.R3261= | Silent (SNP) | VAF 32/272 reads (12%) | catalogued as COSV100912392; called by muse, mutect2, varscan2
- FLVCR2 | c.834T>C p.Y278= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99471653; called by muse, mutect2, varscan2
- FNDC11 | c.594G>A p.P198= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs764814858, COSV100918851; called by muse, mutect2, varscan2
- FYN | c.708A>G p.A236= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99992696; called by muse, mutect2, varscan2
- FZD2 | c.1311G>A p.S437= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV59529135; called by muse, mutect2, varscan2
- GABRR3 | c.1170C>T p.S390= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs761320459, COSV101512288; called by muse, varscan2
- GANAB | c.96T>C p.A32= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100648254; called by muse, mutect2
- GIMAP2 | c.996C>T p.R332= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99785566; called by muse, mutect2, varscan2
- GOLGA7B | c.36G>A p.R12= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV101002421; called by muse, mutect2, varscan2
- GPC2 | c.816C>T p.C272= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99445191; called by muse, mutect2, varscan2
- GPM6B | c.471C>T p.P157= | Silent (SNP) | VAF 7/72 reads (10%) | catalogued as rs755355540, COSV100366613, COSV57421603; called by muse, mutect2, varscan2
- GPR26 | c.555C>T p.F185= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99501176; called by muse, mutect2, varscan2
- GPR82 | c.150G>A p.T50= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1464667118, COSV56887726; called by mutect2, varscan2
- GRM8 | c.489T>C p.A163= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100286779; called by muse, mutect2, varscan2
- GSN | c.315C>T p.N105= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs146365204; called by muse, mutect2, varscan2
- HIPK1 | c.3363T>G p.A1121= (on ENST00000369558 / NM_001369806.1; = p.A727= on NM_181358.2) | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100479775; called by muse, mutect2
154 further variants in this file (0 protein-altering or splice-affecting, 124 silent, 30 other) are not listed here.
